Somatic mutation profile of tumor specimen TCGA-4Z-AA83-01A (aliquot TCGA-4Z-AA83-01A-11D-A391-08) from TCGA case TCGA-4Z-AA83, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.8 years (19,280 days).
Specimen TCGA-4Z-AA83-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abe1e66a-ecca-4d19-be77-b6e269a9068b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA83-10A (Blood Derived Normal), aliquot TCGA-4Z-AA83-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1aaa309-f4c0-4fef-8d5f-87400e6fc273

The open-access MAF lists 95 somatic variants for this specimen: 67 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 27, Nonsense Mutation 8, Frame Shift Del 2, Splice Region 1, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1294C>G p.Q432E (on ENST00000272895 / NM_173076.3; = p.Q114E on NM_015657.3) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV55964723; called by muse, mutect2, varscan2
- ABCB10 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV104419269, COSV60621933; called by muse, mutect2, varscan2
- ADGRE3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV53732007; called by muse, mutect2, varscan2
- APLP1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs781528434, COSV55701542; called by muse, mutect2, varscan2
- ARID2 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | catalogued as COSV100535685; called by muse, mutect2, varscan2
- ATP8B1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV52175036; called by muse, mutect2, varscan2
- BRD8 | c.2492G>A p.R831Q (on ENST00000254900 / NM_139199.2; = p.R904Q on NM_006696.4) | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50154907; called by muse, mutect2, varscan2
- C3orf20 | c.1822C>G p.Q608E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV53786549; called by muse, mutect2, varscan2
- CCDC110 | c.2248G>A p.V750I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as rs767005070, COSV56872076; called by muse, mutect2, varscan2
- CCDC18 | c.2736G>C p.K912N (on ENST00000343253 / NM_001306076.1; = p.K913N on NM_206886.4) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV58144842; called by muse, varscan2
- CCT6B | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV58489951; called by muse, mutect2, varscan2
- CDK13 | c.2633G>A p.W878* | Nonsense Mutation (SNP) | VAF 121/312 reads (39%) | catalogued as COSV51698286, COSV99475253; called by muse, mutect2, varscan2
- CHRND | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs145920855, COSV51321142; called by muse, mutect2, varscan2
- CNTN6 | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as rs371274615, COSV63177615; called by muse, mutect2, varscan2
- CUBN | c.6545C>G p.S2182* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs745572778, COSV100912288; called by muse, mutect2, varscan2
- DBF4B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59261586; called by muse, mutect2, varscan2
- DVL2 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs752593583, COSV50035200; called by muse, mutect2, varscan2
- EPS15 | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV65543350; called by muse, mutect2, varscan2
- ERBIN | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773910654, COSV52320180; called by muse, mutect2, varscan2
- ESPL1 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57760405; called by muse, mutect2, varscan2
- FAM83D | c.1232C>A p.T411N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV54158030; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as rs202205355, COSV58545193; called by muse, mutect2, varscan2
- GABRA4 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as COSV51930515; called by muse, mutect2, varscan2
- GLIPR1L2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV57554710; called by muse, mutect2, varscan2
- GPANK1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs757605253, COSV63263895; called by muse, mutect2, varscan2
- GRIA2 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52382537, COSV52395587; called by muse, mutect2, varscan2
- GRM5 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV59612192; called by muse, mutect2, varscan2
- H2AZ1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV56455518; called by muse, mutect2, varscan2
- HRNR | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs201797889; called by muse, mutect2, varscan2
- INTS6 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60879022; called by muse, mutect2, varscan2
- KCNJ4 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57857649; called by muse, mutect2, varscan2
- KCNV1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747782041, COSV52087001; called by muse, mutect2, varscan2
- KDM6A | c.1581_1587del p.A529Hfs*17 | Frame Shift Del (DEL) | VAF 25/33 reads (76%) | catalogued as COSV65042315; called by mutect2, pindel, varscan2
- KRT20 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs1322970219, COSV51424721; called by muse, mutect2, varscan2
- MCM4 | c.2207C>G p.S736* | Nonsense Mutation (SNP) | VAF 61/174 reads (35%) | catalogued as COSV100031336, COSV100031421; called by muse, mutect2, varscan2
- MYBL1 | c.1822G>C p.A608P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV72919054; called by muse, varscan2
- NOTCH4 | c.5219G>A p.W1740* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV66680911; called by muse, mutect2, varscan2
- NRG1 | c.1400C>T p.A467V (on ENST00000405005 / NM_013964.5; = p.A472V on NM_013956.5) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs774365052, COSV55147001; called by muse, mutect2, varscan2
- NUDT17 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57907702; called by muse, mutect2, varscan2
- OAS3 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 62/167 reads (37%) | catalogued as COSV99966145; called by muse, mutect2, varscan2
- PCED1A | c.95A>C p.N32T | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62313889; called by muse, mutect2, varscan2
- PDE1A | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV59527235, COSV59537487; called by muse, mutect2, varscan2
- PDZD4 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs1557075593, COSV99381157; called by muse, mutect2, varscan2
- PIKFYVE | c.5156C>T p.P1719L | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); catalogued as rs1343940228, COSV52243894; called by muse, mutect2, varscan2
- POLE4 | c.342T>C p.G114= | Splice Region (SNP) | VAF 78/217 reads (36%) | catalogued as COSV52051421; called by muse, mutect2, varscan2
- PTGER2 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs1191198533, COSV55419299; called by muse, mutect2, varscan2
- RARA | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54191803, COSV54193672, COSV99565431; called by muse, mutect2, varscan2
- ROS1 | c.2380G>T p.V794L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV63856967; called by muse, mutect2, varscan2
- RSRC1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.439); catalogued as rs756866968, COSV55832052; called by muse, mutect2, varscan2
- SCN8A | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV100633511; called by muse, mutect2
- SDAD1 | c.1854+1G>A p.X618_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV62403161; called by muse, mutect2, varscan2
- SERPINH1 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.759); catalogued as rs1437455313, COSV63998168; called by muse, mutect2, varscan2
- SMAD4 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV61685116, COSV61690444, COSV61691409; called by muse, mutect2, varscan2
- SNRPN | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57596808; called by muse, mutect2, varscan2
- SPTA1 | c.3148C>A p.P1050T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.179); catalogued as COSV63755654; called by muse, mutect2, varscan2
- TARBP1 | c.3859C>T p.R1287* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as rs201259533, COSV50192818, COSV50194605; called by muse, mutect2, varscan2
- TSC1 | c.555C>G p.Y185* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as COSV53765068, COSV53765773, COSV53771625, COSV53775014; called by muse, mutect2, varscan2
- TTN | c.23974G>A p.A7992T (on ENST00000591111; = p.A7065T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | PolyPhen benign (0.015); catalogued as COSV60154743; called by muse, mutect2, varscan2
- TYRO3 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.13); catalogued as COSV55484401; called by muse, mutect2, varscan2
- UBA6 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV59178661; called by muse, mutect2, varscan2
- UGT1A7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368625224, COSV60852795; called by muse, mutect2, varscan2
- ZNF687 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs755339101, COSV55018997; called by muse, mutect2, varscan2
- ZNF700 | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV54310800; called by muse, mutect2, varscan2
- KMT2C | c.8844del p.N2949Ifs*10 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- RAI1 | c.3586dup p.E1196Gfs*21 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1154T>A p.L385Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAMTSL1 | c.75C>A p.T25= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV52818368, COSV99442536; called by muse, mutect2, varscan2
- ASXL3 | c.5823C>T p.P1941= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV52470592; called by muse, mutect2, varscan2
- BMS1 | c.1542A>G p.E514= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1172764250, COSV65734394; called by muse, mutect2, varscan2
- CATSPERB | c.2025G>A p.K675= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV56428935; called by muse, mutect2, varscan2
- CEP164 | c.498C>T p.S166= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs781437579, COSV54042798; called by muse, mutect2, varscan2
- E2F1 | c.1053C>G p.L351= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs775614866, COSV55776943; called by muse, mutect2, varscan2
- ELAVL3 | c.678C>T p.Y226= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs780654110, COSV63646625; called by muse, mutect2, varscan2
- FSTL4 | c.972C>T p.S324= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs190908572; called by muse, mutect2, varscan2
- HDC | c.1836C>T p.V612= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV51073039; called by muse, mutect2, varscan2
- HK3 | c.696G>A p.P232= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs773768207, COSV52841727; called by muse, mutect2, varscan2
- IRF2BPL | c.1140C>T p.L380= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53146020; called by muse, mutect2, varscan2
- IRF9 | c.681C>T p.N227= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs1393144147, COSV60703176, COSV60703470; called by muse, mutect2, varscan2
- KRIT1 | c.1965C>G p.V655= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV60668974; called by muse, mutect2, varscan2
- MYF5 | c.222C>T p.A74= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV57355516; called by muse, mutect2, varscan2
- PLCH2 | c.366C>T p.F122= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99615766; called by muse, mutect2
- PLD2 | c.2559C>T p.N853= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs774751573, COSV54007082; called by muse, mutect2, varscan2
- PLEKHG4B | c.1384C>A p.R462= (on ENST00000283426; = p.R818= on NM_052909.5) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs201663295, COSV52049808; called by muse, varscan2
- POU6F2 | c.144G>A p.A48= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs773995817, COSV68875888; called by muse, mutect2, varscan2
- SLC22A6 | c.879G>A p.R293= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV64560444; called by muse, mutect2, varscan2
- SLC45A1 | c.1536C>T p.L512= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs770426185, COSV57096177, COSV57096819; called by muse, mutect2, varscan2
- SSBP1 | c.429G>A p.Q143= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1226268633, COSV54681484; called by muse, mutect2, varscan2
- STAG2 | c.2394C>T p.F798= | Silent (SNP) | VAF 65/87 reads (75%) | catalogued as COSV54363422; called by muse, mutect2, varscan2
- STAG2 | c.2502C>T p.F834= | Silent (SNP) | VAF 50/65 reads (77%) | catalogued as COSV54363439; called by muse, mutect2, varscan2
- TTN | c.87411A>T p.T29137= (on ENST00000591111; = p.T21713= on NM_003319.4) | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV60154704; called by muse, mutect2, varscan2
- VPS13B | c.9831T>C p.F3277= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV62147177; called by muse, mutect2, varscan2
- ZNF208 | c.78G>A p.Q26= | Silent (SNP) | VAF 83/178 reads (47%) | catalogued as COSV68108801; called by muse, mutect2, varscan2
- ZNF799 | c.72T>C p.C24= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV101345249; called by mutect2, varscan2
- P4HA1 | c.1148+1051G>A | Intron (SNP) | VAF 24/167 reads (14%) | catalogued as COSV54962744; called by muse, mutect2, varscan2
